MMRF case MMRF_1955 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3d76ac74-5848-4e34-90ce-33c1beb88912

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 483 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,822 days); ISS stage: III; Days to last known disease status: 483 days (1.3 years); Days to last follow up: 483 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 162 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 483.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1980 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 9.16 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 36.5 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 332 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.73 mmol/L; Albumin 42 g/L; Total Protein 8.4 g/dL; Glucose 6.05 mmol/L.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 0.593 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 19 ×10⁹/L; Absolute Neutrophil 16.9 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 265 µmol/L; Blood Urea Nitrogen 27.1 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.
- Day 172 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 2.37 g/L; Immunoglobulin A 0.801 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 6.05 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 17.6 ×10⁹/L; Absolute Neutrophil 16.3 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 163 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 10.3 mmol/L.
- Day 291 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 2.76 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.246 g/L; Lactate Dehydrogenase 4.73 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 11.5 ×10⁹/L; Platelets 369 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 9.41 mmol/L.
- Day 354 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.1 mg/dL; Immunoglobulin G 5.64 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 0.372 g/L; Lactate Dehydrogenase 5.58 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 16.1 ×10⁹/L; Absolute Neutrophil 14.8 ×10⁹/L; Platelets 341 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 8.09 mmol/L.
- Day 427 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.5 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 2.48 g/L; Immunoglobulin M 0.251 g/L; Lactate Dehydrogenase 12.9 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 12.6 ×10⁹/L; Absolute Neutrophil 11.6 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 29 g/L; Total Protein 7.7 g/dL; Glucose 4.51 mmol/L.

Other clinical attributes
- Day 1: Weight: 97 kg; Height: 153 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1955_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1955_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
